Surgical pathology report (de-identified scan), TCGA case TCGA-FK-A3SD, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-FK-A3SD-01A (Primary Tumor).

- LAB RESULTS

		3/30/12

SURG PATH REPORT
COLLECTION DATE/TIME:

PATH#:

Specimen collected on ()
Accessioned on ()

FINAL DIAGNOSIS ----- Pathologist:
LEFT THYROID (COMPLETION LOBECTOMY): INCIDENTAL PAPILLARY
MICROCARCINOMA (1 MM) IN A BACKGROUND OF MULTINODULAR HYPERPLASIA.
SEE NOTE.

NOTE: Representative sections were reviewed at the daily quality
assurance conference.

Reported by:

Final Report Signed on ()

ICD-O-3
carcinoma, papillary, thyroid
8240/3
Site: thyroid, NOS
C73A 5-M2
R0

*** Unofficial lab results - do not file in patient chart. ***
*** Contact medical records for official chart copy. ***
ENTER OTHER NOTES ON THE DETAIL PAGE. ALL LAB RESULTS PERFORMED AT:

Source: NCI Genomic Data Commons file a99df37d-f8d7-40ef-ab2b-dfb371e95b79 (TCGA-FK-A3SD.6E68253F-66C4-4B31-95F5-C1B2BD3009BF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).